Gene-level copy-number profile of tumor specimen TCGA-BR-4369-01A from TCGA case TCGA-BR-4369, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; Tumor grade: G3; Age at diagnosis: 75.3 years (27,509 days).
Specimen TCGA-BR-4369-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.edbae659-df52-40a5-996e-dcb5bc286ba9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-4369-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3b72ab80-9a43-4c1f-ba26-ca5cd8238da3

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 4; copy number 2: 2,635; copy number 3: 11,737; copy number 4: 12,486; copy number 5: 13,665; copy number 6: 12,834; copy number 7: 2,024; copy number 8: 1,124; copy number 9: 295; copy number 10: 786; copy number 11: 623; copy number 12: 1,019; copy number 14: 113; copy number 15: 183; copy number 17: 77; copy number 18: 4; copy number 20: 105; copy number 23: 75; copy number 38: 5; copy number 50: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-4369-01A-01D-1155-01): tumor purity 0.4, ploidy 4.41, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr20:14,757,563–14,758,056, 1 gene: RPS10P2.
- chr20:15,280,764–15,280,873, 1 gene: RNA5SP475.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 2,223 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:36,088,892–36,483,278, 17 genes, copy number 11–12: ADPRS, COL8A2, TRAPPC3, MAP7D1, RN7SL131P, THRAP3, UBE2V2P4, SH3D21, EVA1B, AL591845.1, STK40, LSM10, RNU4-27P, OSCP1, SNORA63C, MRPS15, CSF3R.
- chr7:52,891,837–56,116,417, 70 genes, copy number 20–50 (broad region; genes not listed).
- chr7:65,141,032–68,036,917, 79 genes, copy number 11–23 (broad region; genes not listed).
- chr7:71,779,491–73,403,889, 45 genes, copy number 11–18 (within-gene range 5–18): CALN1, RNA5SP232, AC005011.1, ABCF2P2, TYW1B, MIR4650-2, AC211469.2, AC211469.1, RN7SL377P, SBDSP1, RN7SL625P, SPDYE7P, POM121, AC211476.2, NSUN5P2, AC211476.6, TRIM74, STAG3L3, AC211476.1, Y_RNA, PMS2P7, Y_RNA, SPDYE8, PMS2P8, Y_RNA, AC211476.5, AC211476.3, SPDYE11, AC211476.4, Y_RNA, SPDYE9, PMS2P6, Y_RNA, SPDYE10P, GTF2IP4, PHBP5, NCF1B, GTF2IRD2P1, POM121B, NSUN5, TRIM50, AC211485.1, FKBP6, RNU6-1080P, Y_RNA.
- chr8:68,695,643–95,156,685, 409 genes, copy number 11–12 (broad region; genes not listed).
- chr8:95,206,876–95,216,525, 1 gene, copy number 11: LINC01298.
- chr12:9,594,551–9,818,025, 13 genes, copy number 12: KLRB1, RNU6-700P, GOT2P3, AC010186.4, AC010186.1, AC010186.2, AC010186.3, CLEC2D, NPM1P7, LINC02390, CLECL1, CD69, GCNAP1.
- chr12:57,738,013–57,984,761, 23 genes, copy number 20 (within-gene range 4–20): TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2.
- chr12:67,929,235–68,971,570, 35 genes, copy number 11–15 (within-gene range 5–15): LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.
- chr12:70,515,870–71,118,247, 8 genes, copy number 15 (within-gene range 5–15): PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2.
- chr17:28,755,978–29,930,276, 54 genes, copy number 12 (within-gene range 5–12): FAM222B, RPL31P58, Y_RNA, AC024267.2, ERAL1, AC024267.1, MIR451A, MIR451B, MIR144, MIR4732, FLOT2, AC024267.3, AC024267.6, DHRS13, PHF12, AC024267.4, AC024267.5, PIPOX, SEZ6, AC024619.2, AC024619.1, AC024619.4, MYO18A, TIAF1, AC024619.3, AC005412.1, TWF1P1, CRYBA1, NUFIP2, RPL35AP35, AC068025.2, AC068025.1, RNU4-34P, TAOK1, MIR4523, RNU6-711P, RNU6-1034P, ABHD15, ABHD15-AS1, TP53I13, AC104564.3, GIT1, ANKRD13B, AC104564.4, CORO6, AC104564.2, SSH2, AC104564.1, RNU6-920P, AC104564.5, RPL21P123, AC023389.1, AC023389.2, SNORA70.
- chr17:36,591,879–41,930,542, 260 genes, copy number 12–15 (within-gene range 5–15) (broad region; genes not listed).
- chr17:46,193,576–47,624,665, 43 genes, copy number 14 (within-gene range 5–14): KANSL1-AS1, Y_RNA, MAPK8IP1P1, AC005829.2, AC005829.1, ARL17B, LRRC37A, RN7SL656P, NSFP1, RDM1P2, LRRC37A2, ARL17A, RN7SL199P, FAM215B, NSF, RPS7P11, WNT3, WNT9B, LINC01974, AC005670.1, RNU6ATAC3P, GOSR2, AC005670.2, MIR5089, RPRML, LRRC37A17P, AC005670.3, RN7SL270P, CDC27, AC002558.1, AC002558.3, AC002558.2, MYL4, ITGB3, AC068234.1, RNU7-186P, AC068234.2, THCAT158, EFCAB13, AC040934.1, MRPL45P2, NPEPPS, Y_RNA.
- chr17:48,382,371–53,106,358, 168 genes, copy number 14–20 (broad region; genes not listed).
- chr18:2,506,628–5,630,700, 68 genes, copy number 11 (within-gene range 8–11) (broad region; genes not listed).
- chr19:36,182,276–39,270,188, 136 genes, copy number 11 (broad region; genes not listed).
- chr20:31,274,170–62,841,159, 794 genes, copy number 12–20 (within-gene range 10–20) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
